Somatic mutation profile of tumor specimen HCM-BROD-0036-C41-86M (aliquot HCM-BROD-0036-C41-86M-01D-A937-36) from HCMI case HCM-BROD-0036-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 13.7 years (4,997 days).
Specimen HCM-BROD-0036-C41-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046db283-f369-4440-801e-a94aad176a8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0036-C41-10A (Blood Derived Normal), aliquot HCM-BROD-0036-C41-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15d433d6-6166-442b-80ff-645858eca5d8

The open-access MAF lists 110 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 22, Intron 8, Frame Shift Del 6, Nonsense Mutation 4, 3'UTR 3, Splice Site 2, Splice Region 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 23/733 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053373, CM125342, CM1513639, COSV64813774; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 214/478 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 369/699 reads (53%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.117G>C p.W39C | Missense Mutation (SNP) | VAF 193/375 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56644907; called by muse, mutect2, varscan2
- APOA4 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 180/300 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs184083285; called by muse, mutect2, varscan2
- CELSR2 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 214/446 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.822); catalogued as COSV54769425; called by muse, mutect2, varscan2
- CGN | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 138/668 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555535949, COSV54968420; called by muse, mutect2, varscan2
- COL17A1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 172/389 reads (44%) | catalogued as rs1564685400, CM114989, COSV100793128; called by muse, varscan2
- DNAH7 | c.7397G>A p.R2466H | Missense Mutation (SNP) | VAF 230/497 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770220298, COSV56756557, COSV56767044; called by muse, mutect2, varscan2
- DTNA | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 41/666 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954418044, COSV51998737; called by muse, mutect2
- FAAH | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 190/378 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1321124174; called by muse, mutect2, varscan2
- FLG2 | c.2821A>C p.S941R | Missense Mutation (SNP) | VAF 40/910 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs776813566, COSV101165894, COSV66168956; called by muse, mutect2
- GRM6 | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 249/521 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747287686; called by muse, mutect2, varscan2
- HNRNPU | c.2023G>T p.A675S (on ENST00000283179; = p.A737S on NM_004501.3) | Missense Mutation (SNP) | VAF 177/575 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV51694757; called by muse, mutect2, varscan2
- IGFLR1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.441); catalogued as rs140797969; called by muse, mutect2, varscan2
- IL36A | c.415A>T p.I139F | Missense Mutation (SNP) | VAF 201/409 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52083843; called by muse, mutect2, varscan2
- KDM2B | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 175/327 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65640595; called by muse, mutect2, varscan2
- MACROH2A2 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 201/441 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57159781; called by muse, mutect2, varscan2
- MADCAM1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 74/850 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs762606364, COSV53130416; called by muse, mutect2
- MAML3 | c.2453C>G p.A818G | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.396); catalogued as rs1351468010; called by muse, mutect2
- NEU2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 271/555 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52093247; called by muse, mutect2, varscan2
- OR1E1 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 261/558 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs763721339; called by muse, mutect2, varscan2
- PAX7 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 310/619 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs1268130256; called by muse, mutect2, varscan2
- PCDHGB2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 236/557 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV54043492; called by muse, mutect2, varscan2
- POPDC3 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs369322692; called by muse, mutect2, varscan2
- PRSS21 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 223/436 reads (51%) | catalogued as rs769176365; called by muse, mutect2, varscan2
- SAMD8 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.441); catalogued as rs1325826383; called by muse, mutect2, varscan2
- SAMD9L | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 173/505 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59082965; called by muse, mutect2, varscan2
- SLC35G1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 223/495 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1005579535; called by muse, mutect2, varscan2
- SNAP25 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 252/448 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs774645750, COSV54776523; called by muse, mutect2, varscan2
- STAG2 | c.2594T>G p.L865R | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54364299; called by muse, mutect2, varscan2
- TEKT1 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 166/361 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1323028482, COSV58622482; called by muse, mutect2, varscan2
- THAP12 | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 37/459 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs9666739; called by muse, mutect2
- VSTM5 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs966454235; called by muse, mutect2, varscan2
- ZBED1 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 22/904 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs768804253; called by muse, mutect2
- BBS12 | c.1828T>G p.S610A | Missense Mutation (SNP) | VAF 169/345 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEP350 | c.7501G>C p.D2501H | Missense Mutation (SNP) | VAF 73/545 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTNND2 | c.3119C>G p.S1040C | Missense Mutation (SNP) | VAF 152/319 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DDX60L | c.4983_4985delinsTT p.Q1661Hfs*7 | Frame Shift Del (DEL) | VAF 98/239 reads (41%) | called by pindel, varscan2*
- DNAH6 | c.8981G>A p.G2994E | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF1 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF1 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD3 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FAM13A | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IRX1 | c.277-2A>C p.X93_splice | Splice Site (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- LRRC66 | c.2415G>A p.W805* | Nonsense Mutation (SNP) | VAF 51/494 reads (10%) | called by muse, mutect2, varscan2
- MOAP1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 36/683 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.04); called by muse, mutect2
- MTSS2 | c.1471+2C>T p.X491_splice | Splice Site (SNP) | VAF 13/404 reads (3%) | called by muse, mutect2
- NBEAL1 | c.395del p.S132Tfs*18 | Frame Shift Del (DEL) | VAF 84/231 reads (36%) | called by mutect2, pindel, varscan2
- NECTIN1 | c.1063G>C p.A355P | Missense Mutation (SNP) | VAF 62/492 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10A5 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR10AG1 | c.770A>C p.Q257P | Missense Mutation (SNP) | VAF 17/457 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- OS9 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PARM1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB2 | c.2047_2053dup p.V685Dfs*23 | Frame Shift Ins (INS) | VAF 70/304 reads (23%) | called by mutect2, varscan2
- PTER | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RET | c.2399T>C p.L800P | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHBG | c.454del p.L152Cfs*25 | Frame Shift Del (DEL) | VAF 195/740 reads (26%) | called by mutect2, pindel, varscan2
- ROS1 | c.1901T>C p.L634P | Missense Mutation (SNP) | VAF 171/364 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SDAD1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- SH3PXD2A | c.28_32del p.T10Gfs*23 | Frame Shift Del (DEL) | VAF 157/354 reads (44%) | called by mutect2, pindel, varscan2
- SMG1 | c.2999_3005del p.G1000Vfs*4 | Frame Shift Del (DEL) | VAF 38/235 reads (16%) | called by mutect2, pindel, varscan2
- SOX5 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- SPACA7 | c.276_280del p.S93Efs*4 | Frame Shift Del (DEL) | VAF 55/335 reads (16%) | called by mutect2, pindel, varscan2
- SULT2B1 | c.100T>C p.Y34H (on ENST00000201586 / NM_177973.2; = p.Y19H on NM_004605.2) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2
- TCN1 | c.1003T>A p.S335T | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR5 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- TMEM155 | c.57C>T p.G19= | Splice Region (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2
- TRIM77 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- TTN | c.85527C>A p.H28509Q (on ENST00000591111; = p.H21085Q on NM_003319.4) | Missense Mutation (SNP) | VAF 23/416 reads (6%) | PolyPhen possibly damaging (0.827); called by muse, mutect2
- UBN2 | c.4034A>T p.K1345I | Missense Mutation (SNP) | VAF 290/442 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VCAN | c.7505C>A p.P2502Q | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2
- WDR17 | c.2627A>C p.K876T | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZFY | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.292); called by muse, mutect2
- ZNF462 | c.226A>T p.N76Y | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF569 | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CENPC | c.1476G>A p.K492= | Silent (SNP) | VAF 130/293 reads (44%) | called by muse, mutect2, varscan2
- CERS2 | c.285C>T p.P95= | Silent (SNP) | VAF 97/501 reads (19%) | called by muse, mutect2, varscan2
- DIDO1 | c.984T>C p.T328= | Silent (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- DNAH17 | c.9442C>T p.L3148= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as rs939827414; called by muse, mutect2
- ENPP2 | c.1983G>A p.P661= (on ENST00000075322 / NM_001040092.3; = p.P713= on NM_006209.5) | Silent (SNP) | VAF 34/449 reads (8%) | catalogued as rs144995678; called by muse, mutect2
- FGF18 | c.279C>T p.F93= | Silent (SNP) | VAF 99/384 reads (26%) | catalogued as rs375630229; called by muse, mutect2, varscan2
- GGT1 | c.1446A>T p.A482= | Silent (SNP) | VAF 355/697 reads (51%) | called by muse, mutect2, varscan2
- HS3ST1 | c.378G>A p.S126= | Silent (SNP) | VAF 136/425 reads (32%) | catalogued as rs190695013, COSV50025408; called by muse, mutect2, varscan2
- MAST4 | c.1408C>A p.R470= (on ENST00000403625 / NM_001164664.2; = p.R281= on NM_015183.3) | Silent (SNP) | VAF 127/272 reads (47%) | catalogued as COSV55121118; called by muse, mutect2, varscan2
- MUC5AC | c.14268A>G p.V4756= | Silent (SNP) | VAF 273/536 reads (51%) | catalogued as rs946035588; called by muse, mutect2, varscan2
- OR5T3 | c.588C>A p.L196= | Silent (SNP) | VAF 15/539 reads (3%) | catalogued as rs374751770, COSV57380253; called by muse, mutect2
- PIK3C2G | c.4197C>T p.G1399= (on ENST00000676171; = p.G1358= on NM_004570.5) | Silent (SNP) | VAF 103/255 reads (40%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1875T>C p.A625= | Silent (SNP) | VAF 21/420 reads (5%) | called by muse, mutect2
- PSMD8 | c.405G>A p.K135= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV53058755; called by muse, mutect2
- RAD51AP2 | c.2007C>A p.S669= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV67588484; called by muse, mutect2, varscan2
- RCAN2 | c.558T>G p.T186= | Silent (SNP) | VAF 76/326 reads (23%) | called by muse, varscan2
- SCARA5 | c.1008G>T p.G336= | Silent (SNP) | VAF 150/323 reads (46%) | called by muse, mutect2, varscan2
- TAF6 | c.1725C>A p.V575= | Silent (SNP) | VAF 177/863 reads (21%) | called by muse, mutect2, varscan2
- TJP1 | c.1122A>G p.R374= | Silent (SNP) | VAF 210/387 reads (54%) | called by muse, mutect2, varscan2
- TMEM11 | c.297G>A p.L99= | Silent (SNP) | VAF 291/559 reads (52%) | catalogued as rs1442295946; called by muse, mutect2, varscan2
- VPS37D | c.237G>A p.R79= | Silent (SNP) | VAF 290/764 reads (38%) | called by muse, mutect2, varscan2
- ZNF516 | c.1419G>A p.A473= | Silent (SNP) | VAF 379/547 reads (69%) | called by muse, mutect2, varscan2
- C1orf141 | c.416+14A>T | Intron (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- DGLUCY | c.257+150del | Intron (DEL) | VAF 150/394 reads (38%) | catalogued as COSV99823910; called by mutect2, pindel, varscan2
- EIF4E | c.*36G>A | 3'UTR (SNP) | VAF 18/98 reads (18%) | catalogued as rs1221893529; called by muse, varscan2
- EPHA1 | c.1337-40T>A | Intron (SNP) | VAF 31/691 reads (4%) | called by muse, mutect2
- GCSAML | c.140-63G>T | Intron (SNP) | VAF 30/194 reads (15%) | called by muse, varscan2
- IL33 | c.*143A>G | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- MOGS | c.777-25T>A | Intron (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- MYLPF | c.-30C>T | 5'UTR (SNP) | VAF 147/326 reads (45%) | catalogued as COSV104394598; called by muse, mutect2, varscan2
- TNNT2 | c.234-23C>G | Intron (SNP) | VAF 140/308 reads (45%) | called by muse, mutect2, varscan2
- TNNT2 | c.234-24G>T | Intron (SNP) | VAF 138/306 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10360+1160A>G | Intron (SNP) | VAF 184/360 reads (51%) | catalogued as rs1405282268; called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 23/192 reads (12%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
